Somatic mutation profile of tumor specimen MP2PRT-PASLRN-TMP1-A (aliquot MP2PRT-PASLRN-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASLRN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,265 days).
Specimen MP2PRT-PASLRN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adc6d78c-20ed-45cd-9190-9150dc328d45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASLRN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASLRN-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c8073b4-7c16-4f8e-a672-28ee19a858bd

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Nonsense Mutation 2, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVPI1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 283/588 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.242); catalogued as rs150249445; called by muse, mutect2, varscan2
- CUX1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 178/394 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1208666189; called by muse, varscan2
- ELF3 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 165/368 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs149305892; called by muse, mutect2, varscan2
- FLNC | c.5797G>A p.D1933N | Missense Mutation (SNP) | VAF 111/252 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs762297336, COSV57951118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPFIA2 | c.2659G>T p.E887* | Nonsense Mutation (SNP) | VAF 81/215 reads (38%) | catalogued as COSV100332887, COSV100336036; called by muse, mutect2, varscan2
- ANKDD1B | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ATAD2 | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATM | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- DNM1L | c.836G>C p.R279T | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV1-2 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2
- JAG1 | c.907C>A p.H303N | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OBSCN | c.12660_12661insTCC p.K4220_G4221insS | In Frame Ins (INS) | VAF 159/353 reads (45%) | called by mutect2, pindel, varscan2
- SACS | c.5402C>G p.S1801* | Nonsense Mutation (SNP) | VAF 15/488 reads (3%) | called by muse, mutect2
- SLC29A3 | c.1215G>C p.K405N | Missense Mutation (SNP) | VAF 176/414 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TTN | c.23854C>G p.P7952A (on ENST00000591111; = p.P7025A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/241 reads (36%) | PolyPhen benign (0.006); called by muse, mutect2
- OPRL1 | c.687C>T p.L229= | Silent (SNP) | VAF 233/501 reads (47%) | catalogued as rs781489806, COSV61091417; called by muse, mutect2, varscan2
- VEPH1 | c.474C>G p.T158= | Silent (SNP) | VAF 108/258 reads (42%) | called by muse, mutect2, varscan2
- WASF3 | c.1281G>A p.A427= | Silent (SNP) | VAF 146/331 reads (44%) | catalogued as rs1007262554, COSV58962244; called by muse, mutect2, varscan2
- HUNK | c.*1554G>C | 3'UTR (SNP) | VAF 128/283 reads (45%) | called by muse, mutect2, varscan2
